Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A5U7, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A5U7-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report (For Collection of Cancerous Tissue)

ICD-O-3
Carcinoma, Squamous
Cell, NOS 8670/3
Site: Middle third of
Esophagus C15.4
Jw 4/16/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator _____

Signature _____

Date _____

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status		Race
	1m69	☒ Single ☒ Married ☐ Divorced ☐ Widow		Vietnamese
Gender	Weight			Blood Pressure
☒ Male ☐ Female	53 kg			13/8
				Heart Rate
				89

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	pain, Trouble swallowing
Symptoms:	weight loss, pain, Vocal changes, Trouble swallowing
Clinical Findings:	
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1 pack/day	23 (yrs)	1/3 (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☐ NO		1 drink/day	21 (yrs)	1/3 (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers: _____					

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy	Squamous cell carcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Esophageal Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2 N0 M0 Stage: II A		

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Resection of 113 esophagus		
Primary Tumor		
Organ	Detailed Location	Size
esophagus TUMOR	middle third	4.5 x 1.5 x 1 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T 2 N 0 M 0		Stage: II A

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
esophageal Tumor	1.5x1.5x1 cm	middle third	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT2 N0 M0		Stage: IIA	
Notes:			

[page 5 of 5]
Consolidated Pathology Diagnosis

Histological Pattern															
Cell Distribution			+ -		Structural Pattern			+ -							
Diffuse					Streaming										
Mosaic			α		Storiform										
Necrosis			α		Fibrosis										
Lymphocytic Infiltration			α		Palisading										
Vascular Invasion				α	Cystic Degeneration										
Clusterized			α		Bleeding										
Alveolar Formation				α	Myxoid Change										
Indian File				α	Psammoma/Calcification										
Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell		α		Glandular cell				Round Cell				Large Cell			
Spindle Cell		α		Cell Stratification				Fibroblast				Small Cell			
Keratin		α		Secretion				Osteoblast				RS Cell/RS Like			
Desmosome		α		Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl		α		Gland formation				Myoblast				Plasma Cell			
Cellular Differentiation: ☒ Well ☐ Moderate ☐ Poor															
Nuclear Appearance															
Nuclear Atypia:								0	I	II	III				
Aniso Nucleosis									α						
Hyperchromatism									α						
Nucleolar Prominent									α						
Multinucleated Giant Cell									α						
Mitotic Activity									α						
Nuclear Grade:									α						

D₁ 85% D₂ 80% D₃ 80% D₄ 50% because 20%

Final Pathology Report

Histological Diagnosis: Squamous Cell Carcinoma **Grade:** 1

Comments:

Director, Research Pathology

INTEGRATED REPORT OF FINDINGS B:

Date

Reviewed (Signature)	Date Reviewed:	2/15/13

Source: NCI Genomic Data Commons file 8a82ad72-00fe-414b-847a-aef3f3cd88a1 (TCGA-LN-A5U7.5D66C90C-40A9-4F40-89FF-EB194FF4A81E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).